Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0YU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0YU-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial carcinoma.

LMP DATE:

PROCEDURE: Robot assisted laparoscopic hysterectomy, bilateral salpingo-oophorectomy and pelvic lymph node dissection.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

OTHER DISEASES: Not answered.

1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium 054.1 *hw* 5/2/11**FINAL DIAGNOSIS:**

PART 1: RIGHT PELVIC LYMPH NODE, DISSECTION -

FIBROADIPOSE TISSUE, NEGATIVE FOR NEOPLASM (ENTIRE SPECIMEN SUBMITTED).

PART 2: LEFT PELVIC LYMPH NODE, DISSECTION -

FIBROADIPOSE TISSUE, NEGATIVE FOR NEOPLASM (ENTIRE SPECIMEN SUBMITTED).

PART 3: UTERUS WITH CERVIX AND BILATERAL ADNEXA, ROBOT-ASSISTED LAPAROSCOPIC HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY (158 GRAMS)-

- A. WELL DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE (FIGO GRADE 1).
- B. TUMOR INVADES LESS THAN 50% INTO THE MYOMETRIUM (ABOUT 25% INVASION).
- C. NO LYMPHOVASCULAR SPACE INVASION.
- D. TUMOR MEASURES 4.5 CM AND INVOLVES ABOUT 90% OF THE ENDOMETRIAL SURFACES.
- E. BACKGROUND COMPLEX ATYPICAL ENDOMETRIAL HYPERPLASIA.
- F. CERVIX, NEGATIVE FOR MALIGNANCY.
- G. BILATERAL OVARIES WITH PHYSIOLOGIC CYSTS, NEGATIVE FOR MALIGNANCY.
- H. RIGHT OVARY WITH ENDOSALPINGIOSIS.
- I. BILATERAL FALLOPIAN TUBES, NEGATIVE FOR MALIGNANCY.
- J. PATHOLOGIC STAGE: pT1a pNX (FIGO STAGE IA).

COMMENT:

Please cross refer the companion pelvic wash specimen [REDACTED] which contained atypical cells (see that report for details). Previous diagnosis of endometrioid adenocarcinoma is noted. [REDACTED]

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

TUMOR TYPE:

SPECIMENS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Endometrioid adenocarcinoma, NOS

Well differentiated (FIGO 1)

ARCHITECTURAL GRADE:

Well differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 45 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90 %, Posterior endomyometrium: 90 %
Less than 1/2 thickness of myometrium

DEPTH OF INVASION:

No

ANGIOLYMPHATIC INVASION:

PRE-NEOPLASTIC CONDITIONS:

Complex endometrial hyperplasia with atypia

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 0

T STAGE, PATHOLOGIC:

pT1a

N STAGE, PATHOLOGIC:

pNX

M STAGE, PATHOLOGIC:

Not applicable

FIGO STAGE:

IA

hw 5/2/11

Source: NCI Genomic Data Commons file 9a10941d-3b95-440c-9cea-8e024ddc09ef (TCGA-BG-A0YU.5E3AA4BA-20F6-4241-AD70-8E5DEDA9D129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).